Somatic mutation profile of tumor specimen MBCproject_0095_T3_WES (aliquot MBCproject_0095_T3_WES_1) from CMI case MBCproject_0095, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 32.1 years (11,708 days).
Specimen MBCproject_0095_T3_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af6abc6f-1718-47f3-9f1c-9b2c89a7113f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCproject_0095_SALIVA (Saliva), aliquot MBCproject_0095_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b576aa43-ca69-4e70-8a35-cccf62e6c9f3

The open-access MAF lists 124 somatic variants for this specimen: 84 protein-altering or splice-affecting, 25 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 25, Intron 7, Frame Shift Del 4, 3'UTR 3, In Frame Del 3, RNA 3, Splice Site 2, Nonsense Mutation 1, Splice Region 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD1 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as rs371626040; called by muse, mutect2, varscan2
- C12orf56 | c.1459A>G p.T487A (on ENST00000543942 / NM_001170633.2; = p.T327A on NM_001099676.3) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as rs1385655558; called by muse, mutect2
- CCNT1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.684); catalogued as rs1565619651; called by muse, mutect2
- CHAF1A | c.594C>G p.D198E | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as COSV56670098; called by muse, mutect2, varscan2
- COL4A2 | c.4229G>A p.R1410Q | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.19); catalogued as rs1004346642, COSV64629756; called by muse, mutect2
- CRYBG1 | c.3013C>G p.P1005A | Missense Mutation (SNP) | VAF 26/281 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs757248679, COSV100954615; called by muse, mutect2
- DNMT1 | c.2548G>C p.D850H | Missense Mutation (SNP) | VAF 23/298 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV61585038; called by muse, mutect2
- ERVMER34-1 | c.557G>A p.W186* | Nonsense Mutation (SNP) | VAF 63/233 reads (27%) | catalogued as COSV66920659; called by muse, mutect2, varscan2
- GIMAP7 | c.193C>G p.P65A | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761682617, COSV57960087; called by muse, mutect2, varscan2
- LARGE1 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 62/542 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1263627262; called by muse, mutect2, varscan2
- MAP3K5 | c.3940A>T p.T1314S | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs975901668; called by muse, mutect2
- MFRP | c.65G>T p.S22I (on ENST00000449574; = p.S404I on NM_031433.4) | Missense Mutation (SNP) | VAF 13/345 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs991249582, COSV64128556; called by muse, mutect2
- MUC5B | c.11496C>A p.H3832Q | Missense Mutation (SNP) | VAF 63/467 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as COSV101500659; called by muse, mutect2, varscan2
- MYO3A | c.4490G>A p.R1497Q | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.003); catalogued as rs375133744; called by muse, mutect2
- PLEKHA7 | c.2094C>G p.F698L | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63044368; called by muse, mutect2, varscan2
- PLXNA4 | c.2626del p.V876Sfs*29 | Frame Shift Del (DEL) | VAF 69/298 reads (23%) | catalogued as COSV58170160; called by mutect2, pindel, varscan2
- PMS2 | c.1960C>G p.P654A | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.336); catalogued as COSV56225140; called by muse, mutect2, varscan2
- PRDX3 | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 24/241 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs151214527; called by muse, mutect2, varscan2
- RBM26 | c.1325A>G p.N442S | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs1324476788; called by muse, mutect2, varscan2
- RGS7 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 35/332 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs749609576, COSV100470752, COSV58543385; called by muse, mutect2, varscan2
- ROBO2 | c.3361G>C p.E1121Q | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV100166803; called by muse, mutect2, varscan2
- SLC4A3 | c.841C>G p.R281G | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV56094705; called by muse, mutect2, varscan2
- SOX5 | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.085); catalogued as COSV58645781; called by muse, mutect2, varscan2
- TP53 | c.293del p.P98Lfs*25 | Frame Shift Del (DEL) | VAF 47/147 reads (32%) | catalogued as COSV52850165; called by mutect2, pindel, varscan2
- TULP3 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs151311529; called by muse, mutect2, varscan2
- ACER3 | c.454T>G p.L152V | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ANOS1 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- BZW2 | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2
- C12orf56 | c.829T>C p.Y277H | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- C4BPA | c.663T>G p.N221K | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CCDC191 | c.971A>C p.Q324P | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- CD109 | c.641C>G p.T214R | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.155); called by muse, mutect2
- CORIN | c.522_533del p.F175_L178del | In Frame Del (DEL) | VAF 29/186 reads (16%) | called by mutect2, pindel, varscan2
- CPS1 | c.3617C>G p.A1206G | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CPT1A | c.824C>G p.A275G | Missense Mutation (SNP) | VAF 23/415 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- CROCC2 | c.2815C>A p.H939N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.018); called by muse, varscan2
- DDC | c.407A>T p.K136I | Missense Mutation (SNP) | VAF 20/402 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.354); called by muse, mutect2
- DDX6 | c.551G>C p.C184S | Missense Mutation (SNP) | VAF 37/351 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DENND1B | c.819+1G>T p.X273_splice | Splice Site (SNP) | VAF 50/415 reads (12%) | called by muse, mutect2, varscan2
- DRD4 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- EIF2B5 | c.1450G>C p.D484H (on ENST00000647909; = p.D476H on NM_003907.3) | Missense Mutation (SNP) | VAF 52/540 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- ENKUR | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- ENTPD7 | c.1333C>A p.Q445K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, varscan2
- ERICH6 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 12/245 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, mutect2
- F13B | c.1348T>G p.C450G | Missense Mutation (SNP) | VAF 13/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FBXL21P | n.974G>C | Splice Region (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- GALK1 | c.773T>G p.V258G | Missense Mutation (SNP) | VAF 27/503 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2
- GDF1 | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- GFUS | c.826T>A p.S276T | Missense Mutation (SNP) | VAF 28/456 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.15); called by muse, mutect2
- GFY | c.256A>C p.T86P | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.385); called by muse, mutect2
- GGT5 | c.1561A>G p.I521V | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.074); called by muse, mutect2
- GMDS | c.1039C>G p.P347A | Missense Mutation (SNP) | VAF 23/448 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2
- GRIA4 | c.1113T>A p.N371K | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- KDR | c.379_414del p.A127_I138del | In Frame Del (DEL) | VAF 46/324 reads (14%) | called by mutect2, pindel
- LARS1 | c.2428C>G p.Q810E (on ENST00000394434 / NM_020117.11; = p.Q783E on NM_016460.3) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LCT | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 45/459 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- MCEE | c.41-14_44del p.X14_splice | Splice Site (DEL) | VAF 24/248 reads (10%) | called by mutect2, pindel
- MINK1 | c.3424G>A p.A1142T | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NPTX2 | c.345_353del p.D115_R118delinsE | In Frame Del (DEL) | VAF 17/132 reads (13%) | called by mutect2, pindel*, varscan2
- OPTN | c.1154A>C p.K385T | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- PCDHGB5 | c.1452_1483del p.Y485Gfs*22 | Frame Shift Del (DEL) | VAF 56/294 reads (19%) | called by mutect2, pindel
- PKD2L1 | c.369C>G p.S123R | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- POSTN | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRDM8 | c.1670G>T p.G557V | Missense Mutation (SNP) | VAF 44/457 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2
- RABGAP1 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.4); called by muse, mutect2
- RANBP2 | c.8539G>A p.G2847R | Missense Mutation (SNP) | VAF 50/534 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RECQL5 | c.924G>T p.E308D | Missense Mutation (SNP) | VAF 71/414 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SEMA3A | c.468G>C p.K156N | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- SLC2A14 | c.426A>T p.E142D | Missense Mutation (SNP) | VAF 23/270 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.378); called by muse, mutect2
- SLC9A1 | c.1299_1318del p.W434Yfs*38 | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- SLFN12 | c.1488G>C p.K496N | Missense Mutation (SNP) | VAF 58/349 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SNIP1 | c.576G>C p.R192S | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPRED3 | c.1016T>C p.L339P | Missense Mutation (SNP) | VAF 14/315 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SRP54 | c.837A>G p.I279M | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- TMBIM1 | c.645C>G p.D215E | Missense Mutation (SNP) | VAF 95/286 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TRPM4 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- TRPV2 | c.1110G>A p.M370I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- TTC13 | c.137C>G p.T46S | Missense Mutation (SNP) | VAF 64/300 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); called by muse, varscan2
- UPK2 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VPS13D | c.5428A>C p.I1810L | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ZFP36L2 | c.348G>C p.E116D | Missense Mutation (SNP) | VAF 80/1056 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.949); called by muse, mutect2
- ZNF423 | c.464T>A p.F155Y (on ENST00000563137 / NM_001379286.1; = p.F147Y on NM_015069.4) | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF813 | c.1392G>C p.E464D | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2
- ZSCAN18 | c.200T>A p.L67Q | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACVR2A | c.867G>C p.L289= | Silent (SNP) | VAF 12/193 reads (6%) | called by muse, mutect2
- ASB10 | c.1378C>T p.L460= (on ENST00000420175 / NM_001142459.2; = p.L445= on NM_080871.4) | Silent (SNP) | VAF 34/302 reads (11%) | called by muse, mutect2, varscan2
- B3GALNT1 | c.468C>G p.T156= | Silent (SNP) | VAF 32/328 reads (10%) | called by muse, mutect2, varscan2
- BCAN | c.843T>C p.G281= | Silent (SNP) | VAF 35/227 reads (15%) | called by muse, mutect2, varscan2
- COL28A1 | c.1656C>T p.D552= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as rs751915529, COSV68082134; called by muse, mutect2, varscan2
- CPS1 | c.3618C>A p.A1206= | Silent (SNP) | VAF 31/316 reads (10%) | called by muse, varscan2
- F10 | c.1131C>A p.L377= | Silent (SNP) | VAF 62/1144 reads (5%) | catalogued as COSV100979245; called by muse, mutect2
- FXR2 | c.57C>G p.R19= | Silent (SNP) | VAF 15/167 reads (9%) | called by muse, mutect2
- IRS2 | c.1587G>T p.P529= | Silent (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2
- KIF26B | c.1743C>T p.N581= | Silent (SNP) | VAF 67/322 reads (21%) | catalogued as rs748806574; called by muse, mutect2, varscan2
- LYST | c.3720C>T p.D1240= | Silent (SNP) | VAF 22/234 reads (9%) | called by muse, mutect2
- MAML3 | c.2229C>T p.L743= | Silent (SNP) | VAF 41/690 reads (6%) | catalogued as rs1224908392; called by muse, mutect2
- MEN1 | c.1425G>A p.P475= | Silent (SNP) | VAF 32/311 reads (10%) | catalogued as rs1060503795, COSV53641026; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYBPC3 | c.3661C>T p.L1221= | Silent (SNP) | VAF 44/300 reads (15%) | called by muse, mutect2, varscan2
- OR1K1 | c.669A>T p.A223= | Silent (SNP) | VAF 27/126 reads (21%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1509G>T p.L503= | Silent (SNP) | VAF 222/531 reads (42%) | called by muse, mutect2, varscan2
- PPP4R3B | c.93C>T p.Y31= | Silent (SNP) | VAF 40/410 reads (10%) | called by muse, mutect2
- PPP6R1 | c.2367G>T p.T789= | Silent (SNP) | VAF 6/62 reads (10%) | called by mutect2, varscan2
- RNPS1 | c.624A>C p.V208= | Silent (SNP) | VAF 38/369 reads (10%) | called by muse, mutect2, varscan2
- RPAP1 | c.1665A>G p.T555= | Silent (SNP) | VAF 36/209 reads (17%) | catalogued as rs748137147; called by muse, mutect2, varscan2
- SDK1 | c.5346C>T p.N1782= | Silent (SNP) | VAF 30/400 reads (8%) | catalogued as rs778420128, COSV67364111; called by muse, mutect2
- STRC | c.3856A>C p.R1286= | Silent (SNP) | VAF 22/152 reads (14%) | catalogued as COSV101347997; called by muse, mutect2, varscan2
- TMEM64 | c.378C>G p.V126= | Silent (SNP) | VAF 95/364 reads (26%) | called by muse, mutect2, varscan2
- UNC13A | c.2166G>T p.V722= | Silent (SNP) | VAF 11/115 reads (10%) | called by muse, mutect2
- ZNF783 | c.213G>T p.T71= | Silent (SNP) | VAF 47/364 reads (13%) | catalogued as COSV100954210, COSV100954273; called by muse, mutect2, varscan2
- AZIN1 | chr8:102864451 C>T | 5'Flank (SNP) | VAF 25/121 reads (21%) | catalogued as rs894194981; called by muse, mutect2, varscan2
- BPHL | c.664+553G>A | Intron (SNP) | VAF 22/208 reads (11%) | catalogued as rs1561795530; called by muse, mutect2
- BTNL8 | c.787+28G>C | Intron (SNP) | VAF 22/194 reads (11%) | called by muse, mutect2, varscan2
- DPY19L2P1 | n.1887C>A | RNA (SNP) | VAF 26/240 reads (11%) | called by muse, mutect2, varscan2
- FCRL3 | c.*1951C>A | 3'UTR (SNP) | VAF 21/203 reads (10%) | called by muse, mutect2, varscan2
- ISCU | c.419-30C>T | Intron (SNP) | VAF 24/260 reads (9%) | catalogued as rs1565877307; called by muse, mutect2
- ITPK1 | c.*568A>T | 3'UTR (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- LINC00174 | n.3541C>A | RNA (SNP) | VAF 13/136 reads (10%) | called by muse, mutect2
- MIA2 | c.1955-10T>G | Intron (SNP) | VAF 47/237 reads (20%) | called by muse, mutect2, varscan2
- MRO | c.-30G>C | 5'UTR (SNP) | VAF 19/234 reads (8%) | called by muse, mutect2
- NME4 | c.92-21C>T | Intron (SNP) | VAF 40/246 reads (16%) | called by muse, mutect2, varscan2
- PIGF | c.546+605C>T | Intron (SNP) | VAF 24/124 reads (19%) | catalogued as rs1461461063; called by muse, mutect2, varscan2
- POLR3A | c.1186-41G>C | Intron (SNP) | VAF 30/122 reads (25%) | called by muse, mutect2, varscan2
- PRKCG | c.*49G>C | 3'UTR (SNP) | VAF 42/169 reads (25%) | called by muse, mutect2, varscan2
- SSPOP | n.15716G>C | RNA (SNP) | VAF 18/324 reads (6%) | called by muse, mutect2
